Somatic mutation profile of tumor specimen MP2PRT-PARUBU-TMP1-A (aliquot MP2PRT-PARUBU-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARUBU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,134 days).
Specimen MP2PRT-PARUBU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 077ffd58-b404-4bce-a4a3-a42f30b07a95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUBU-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUBU-NM1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/25338979-d7d7-4eb2-80bf-79de148c1438

The open-access MAF lists 22 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 15, Silent 5, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLCE1 | c.1477C>T p.R493* | Nonsense Mutation (SNP) | VAF 64/241 reads (27%) | catalogued as rs121912601, CM066174, COSV53369456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DUSP8 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 92/942 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs991824356; called by muse, mutect2, varscan2
- KCND2 | c.1673C>T p.T558M | Missense Mutation (SNP) | VAF 21/421 reads (5%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.1); catalogued as rs987040245; called by muse, mutect2
- PNLIPRP2 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as rs1198140788, COSV53942794; called by muse, mutect2, varscan2
- PROX1 | c.1581G>C p.K527N | Missense Mutation (SNP) | VAF 56/459 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV54783011; called by muse, mutect2, varscan2
- SLC17A6 | c.1496C>T p.S499L | Missense Mutation (SNP) | VAF 35/403 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs878877170, COSV54134483; called by muse, mutect2
- TLN2 | c.5117C>T p.S1706L | Missense Mutation (SNP) | VAF 39/306 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.154); catalogued as rs142261304; called by muse, mutect2, varscan2
- ARHGAP4 | c.990T>A p.C330* | Nonsense Mutation (SNP) | VAF 50/680 reads (7%) | called by muse, mutect2
- DISP2 | c.2612T>A p.F871Y | Missense Mutation (SNP) | VAF 144/531 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FAM83B | c.2977G>C p.E993Q | Missense Mutation (SNP) | VAF 69/256 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- GABRQ | c.408G>C p.E136D | Missense Mutation (SNP) | VAF 19/664 reads (3%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.54); called by muse, mutect2
- GLUD2 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 47/322 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KBTBD3 | c.682G>C p.E228Q | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.92); called by muse, mutect2
- KCNT2 | c.2060T>C p.L687P | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- OR10K1 | c.608G>A p.G203D | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); called by muse, mutect2
- PAX1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 59/776 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); called by muse, mutect2
- UBA2 | c.317T>C p.F106S | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK17 | c.1131C>T p.C377= | Silent (SNP) | VAF 20/307 reads (7%) | called by muse, mutect2
- CIITA | c.615C>T p.T205= | Silent (SNP) | VAF 161/399 reads (40%) | catalogued as rs749376450; called by muse, mutect2, varscan2
- ESPL1 | c.2538C>T p.L846= | Silent (SNP) | VAF 38/401 reads (9%) | catalogued as rs761589487; called by muse, mutect2
- PITPNC1 | c.192C>G p.L64= | Silent (SNP) | VAF 37/323 reads (11%) | catalogued as rs774855241; called by muse, mutect2, varscan2
- ZNF423 | c.3840C>T p.T1280= (on ENST00000563137 / NM_001379286.1; = p.T1272= on NM_015069.4) | Silent (SNP) | VAF 40/350 reads (11%) | catalogued as rs779049571, COSV52203337; called by muse, mutect2, varscan2
